Somatic mutation profile of tumor specimen C3N-03933-03 (aliquot CPT0220610006) from CPTAC case C3N-03933, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 70.2 years (25,635 days).
Specimen C3N-03933-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99a517c2-9367-4682-b113-dc9220ba1205.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03933-71 (Blood Derived Normal), aliquot CPT0220710002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa748508-5fdf-4ff6-b43d-1c2ae93d9baa

The open-access MAF lists 68 somatic variants for this specimen: 47 protein-altering or splice-affecting, 15 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 15, Nonsense Mutation 3, Intron 2, 3'Flank 2, 3'UTR 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 276/967 reads (29%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- RHOA | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 18/148 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs1057519951, COSV69041613, COSV69042111, COSV69043712; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 46/488 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ABCC9 | c.2630C>T p.T877M | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs140872303; ClinVar: uncertain significance; called by muse, mutect2
- ARHGAP44 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); catalogued as rs199982507; called by muse, mutect2, varscan2
- ASIC2 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765631881, COSV56758247; called by muse, mutect2, varscan2
- ATM | c.5960C>G p.S1987C | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs1381079714; called by muse, mutect2, varscan2
- C6orf118 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs757080711, COSV57812959; called by muse, mutect2, varscan2
- CASZ1 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs754239516, COSV100682319, COSV59740877; called by muse, mutect2, varscan2
- COPB1 | c.2584T>A p.L862I | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as rs1401063512; called by muse, mutect2
- DLK1 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as rs746155706, COSV100375073, COSV57991318; called by muse, mutect2, varscan2
- FOXO1 | c.1386G>C p.L462F | Missense Mutation (SNP) | VAF 65/477 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65427248; called by muse, mutect2, varscan2
- FRYL | c.2630C>T p.S877L | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1475336154; called by muse, mutect2
- GGT5 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770771145, COSV54071181; called by muse, mutect2
- ILDR1 | c.1437G>T p.W479C (on ENST00000344209 / NM_001199799.2; = p.W435C on NM_175924.4) | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1004936666; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs747954372, COSV99860906; called by muse, mutect2, varscan2
- KCND3 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs761121098, COSV56176281; called by muse, mutect2, varscan2
- MANEA | c.761A>G p.Y254C | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs1381643617, COSV62590177; called by muse, mutect2
- PNLDC1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 29/295 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.248); catalogued as rs202013209; called by muse, mutect2, varscan2
- S100A11 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs200047972; called by muse, mutect2, varscan2
- SMURF2 | c.959A>G p.N320S | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1555685593; called by muse, mutect2, varscan2
- STOX1 | c.2866C>A p.L956I | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs759086040; called by muse, mutect2
- UNC79 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV99829667; called by muse, mutect2
- USH2A | c.13943G>A p.G4648E | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV56375402, COSV56435549; called by muse, mutect2
- VEZT | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201033481; called by muse, mutect2, varscan2
- ADGRB2 | c.4209C>G p.H1403Q | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CAPN3 | c.1198T>C p.S400P | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CASK | c.2716C>A p.L906M (on ENST00000378163 / NM_001367721.1; = p.L901M on NM_003688.3) | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- CASP8 | c.313C>T p.L105F (on ENST00000432109 / NM_033355.3; = p.L137F on NM_001228.4) | Missense Mutation (SNP) | VAF 34/354 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- CGNL1 | c.722C>T p.T241I | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- COL4A1 | c.441+5G>C | Splice Region (SNP) | VAF 43/527 reads (8%) | called by muse, mutect2
- ERN2 | c.1146T>A p.S382R | Missense Mutation (SNP) | VAF 32/382 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2
- FAM120AOS | c.185G>A p.R62K | Missense Mutation (SNP) | VAF 101/518 reads (19%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAM160A1 | c.1115C>A p.T372N | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- GPT | c.1234A>C p.M412L | Missense Mutation (SNP) | VAF 183/1010 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- GUCY2F | c.1839C>A p.F613L | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.302); called by muse, mutect2
- HLA-A | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 60/608 reads (10%) | called by muse, varscan2
- LAMB2 | c.5047del p.T1683Qfs*31 | Frame Shift Del (DEL) | VAF 100/822 reads (12%) | called by mutect2, pindel, varscan2
- LMLN2 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by mutect2, varscan2
- MTBP | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); called by muse, mutect2
- OR14A16 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PPP2R5C | c.1146G>A p.W382* | Nonsense Mutation (SNP) | VAF 16/135 reads (12%) | called by muse, mutect2, varscan2
- PREX2 | c.1322A>T p.N441I | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, varscan2
- SLC23A1 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- SLC6A15 | c.678G>T p.W226C | Missense Mutation (SNP) | VAF 36/376 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- SLIT1 | c.2326G>A p.V776I | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- WNK2 | c.3865G>A p.E1289K | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ACTN4 | c.1599C>T p.Y533= | Silent (SNP) | VAF 46/538 reads (9%) | catalogued as rs1022257383, COSV53143490; called by muse, mutect2
- AMIGO2 | c.1041T>C p.S347= | Silent (SNP) | VAF 22/164 reads (13%) | called by muse, mutect2, varscan2
- DZANK1 | c.909G>A p.L303= (on ENST00000262547 / NM_001099407.1; = p.L104= on NM_018152.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/139 reads (12%) | called by muse, mutect2, varscan2
- FTMT | c.519G>A p.S173= | Silent (SNP) | VAF 42/400 reads (11%) | catalogued as rs772478687, COSV58419816; called by muse, mutect2, varscan2
- GPC5 | c.87C>T p.T29= | Silent (SNP) | VAF 17/255 reads (7%) | called by muse, mutect2
- INTS2 | c.312G>A p.Q104= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs1343146943; called by muse, mutect2, varscan2
- LILRA5 | c.783C>T p.Y261= | Silent (SNP) | VAF 27/151 reads (18%) | catalogued as rs201689439, COSV56642880; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1200C>T p.A400= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2
- MYO15A | c.1920C>T p.D640= | Silent (SNP) | VAF 32/275 reads (12%) | catalogued as rs1203038268; called by muse, mutect2, varscan2
- NXNL2 | c.315G>A p.K105= | Silent (SNP) | VAF 28/355 reads (8%) | called by muse, mutect2
- PLEKHO2 | c.258G>C p.L86= | Silent (SNP) | VAF 36/326 reads (11%) | called by muse, mutect2, varscan2
- PRAME | c.1387C>T p.L463= | Silent (SNP) | VAF 44/500 reads (9%) | catalogued as rs200182963; called by muse, mutect2
- PRAMEF18 | c.823A>C p.R275= | Silent (SNP) | VAF 19/604 reads (3%) | called by muse, mutect2
- SHANK2 | c.2769G>A p.A923= | Silent (SNP) | VAF 26/616 reads (4%) | catalogued as rs575016008, COSV53599569; called by muse, mutect2
- UBL4A | c.279G>A p.P93= | Silent (SNP) | VAF 17/136 reads (13%) | called by muse, mutect2, varscan2
- CCDC39 | chr3:180613824 G>A | 3'Flank (SNP) | VAF 4/32 reads (13%) | catalogued as rs1020825366; called by mutect2, varscan2
- HOXA10 | c.*92_*101del | 3'UTR (DEL) | VAF 38/363 reads (10%) | called by mutect2, pindel
- LCLAT1 | c.743-34072C>T | Intron (SNP) | VAF 12/115 reads (10%) | catalogued as rs779489513, COSV58371106; called by muse, varscan2
- LCN9 | chr9:135666129 C>T | 3'Flank (SNP) | VAF 14/138 reads (10%) | called by mutect2, varscan2
- MRPS28 | c.213+228T>G | Intron (SNP) | VAF 21/291 reads (7%) | called by muse, mutect2
- NLRP2 | c.*8C>T | 3'UTR (SNP) | VAF 34/313 reads (11%) | catalogued as rs1012031597; called by muse, mutect2, varscan2
